Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A6AP, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A6AP-01A (Primary Tumor).

[page 1 of 2]
Ref Physician

SPECIMEN INFORMATION

Collected:
Received:
Reported:

Accession #:
Acct / Reg #

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Right periprostatic tissue: Benign, no pathologic diagnosis.
B. Radical prostatectomy: Carcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, usual type.
2. Prostate size: 30 grams, 4.0 x 3.5 x 3.0 cm.
3. Tumor quantitation: 5% gland volume.
4. Tumor extent: Bilateral, confined to prostate.
5. Perineural invasion: Present.
6. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
7. Extraprostatic extension: Not identified.
8. Seminal vesicle involvement: Not identified.
9. High grade PIN: Present.
10. Lymphovascular space invasion: Not identified.
11. Treatment effect: Not identified.
12. Lymph nodes: Not identified.
13. Other findings: Multifocal chronic prostatitis.
14. pTN stage: pT2c, NX.

CACF ICD-O-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Malignant neoplasm of prostate
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right periprostatic
B. Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two formalin filled containers, each labeled with patient name

A is additionally designated "right periprostatic" and consists of two portions of white-tan to yellow, lobular soft tissue, 0.6 and 0.7 cm. Both are submitted in toto in cassette A1.

Part B is additionally designated "prostate tissue study" and consists of a 30.2 gm (following tissue procurement), 4.0 (right to left) x 3.5 (anterior to posterior) x 3.0 (apex to base) cm prostate with attached bilateral seminal vesicles and vas deferens. The right seminal vesicle is 3.1 x 2.0 x 0.9 cm and the right vas deferens is 5.0 cm in length by 0.4 cm in diameter. The left seminal vesicle is 3.4 x 1.5 x 0.8 cm and the left vas deferens is 3.0 cm in length by 0.5 cm in diameter. The specimen has been inked as follows: right blue, left black. The prostate is serially sectioned from apex to base to reveal a yellow-tan and smooth cut surface. There are focal nodules in the central zone up to 0.5 x 0.5 x 0.5 cm. The peripheral zone is yellow-tan and smooth. A definitive mass is not identified. The seminal vesicles appear free of tumor. Representative sections are submitted in cassettes B1-B14 as follows: A1 is the apical margin coned and then radially sectioned; B2 is the bladder neck margin, coned and then radially sectioned; B3-B4 is apex of the prostate bisected; B5-B8 the mid portion of the prostate submitted right anterior, right posterior, left anterior, left posterior; B9-B12 is the base of the prostate submitted right anterior, right posterior, left anterior, left posterior; B13 is the seminal vesicles at the point of attachment; B14 is additional

[page 2 of 2]
SPECIMEN INFORMATION

representative seminal vesicles. Additionally there are two research cassettes submitted.

All cassettes are labeled 1

Diagnostic Discrepancy		✓
Immunohistochemistry Discrepancy		✓
Pathologic History		✓

Source: NCI Genomic Data Commons file 8ed76926-054d-4ba5-92da-61bf645bbf27 (TCGA-HC-A6AP.7271E139-D1C7-4FB1-B148-54DE4A1DF42B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).